Somatic mutation profile of tumor specimen MBCProject_6127_T1_WES (aliquot MBCProject_6127_T1_WES_1) from CMI case MBCProject_6127, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 38.6 years (14,107 days).
Specimen MBCProject_6127_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82ad55ff-bdcc-4026-a473-0a8d637f99b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6127_SALIVA (Saliva), aliquot MBCProject_6127_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd0a4577-bf9b-440d-b1e2-17e671462640

The open-access MAF lists 42 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, Intron 3, 5'Flank 2, 5'UTR 2, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.402); catalogued as rs765062000; called by muse, mutect2, varscan2
- CSAD | c.794G>A p.R265H (on ENST00000444623 / NM_001244705.2; = p.R292H on NM_015989.5) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs746315360, COSV57241099; called by muse, mutect2, varscan2
- DLG5 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748210887, COSV64948254; called by muse, mutect2, varscan2
- DNAH8 | c.10178C>A p.S3393Y | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59472862; called by muse, mutect2, varscan2
- DNAJC7 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs267604882; called by muse, mutect2, varscan2
- LARP1 | c.2333del p.R778Pfs*27 (on ENST00000518297 / NM_033551.3; = p.R701Pfs*27 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 34/336 reads (10%) | catalogued as COSV60429510; called by mutect2, pindel, varscan2
- LIPA | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1403650234; called by mutect2, varscan2
- RPTOR | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV60818595; called by muse, mutect2
- TRIM2 | c.878C>T p.P293L (on ENST00000437508; = p.P320L on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1279083060, COSV58630714, COSV58631708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR24 | c.1378G>A p.D460N (on ENST00000248142; = p.D330N on NM_032259.4) | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs746133131, COSV50199570; called by muse, mutect2
- AMIGO2 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ATP10D | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CELSR1 | c.4717G>T p.D1573Y | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXM1 | c.2015C>A p.S672* | Nonsense Mutation (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- GJA10 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- HEATR6 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2
- HMGN1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.313); called by muse, varscan2
- JMJD6 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2
- MUC2 | c.2589G>A p.M863I | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.01); called by muse, mutect2
- NF1 | c.8111_8113+5delinsT p.X2704_splice (on ENST00000358273 / NM_001042492.3; = p.X2683_splice on NM_000267.3) | Splice Site (DEL) | VAF 34/133 reads (26%) | called by pindel, varscan2*
- RAB11FIP1 | c.626_627dup p.D210Kfs*78 | Frame Shift Ins (INS) | VAF 25/209 reads (12%) | called by mutect2, pindel, varscan2
- SRRM2 | c.2036G>A p.G679D | Missense Mutation (SNP) | VAF 38/415 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2
- TMA16 | c.406A>C p.N136H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- ADCY2 | c.807G>A p.A269= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs777382356, COSV57903216; called by muse, mutect2, varscan2
- FAT3 | c.7857C>G p.V2619= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2, varscan2
- FOXN4 | c.477T>G p.P159= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
- GTF2H3 | c.297A>T p.G99= | Silent (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- NLGN4X | c.1947C>T p.H649= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99319414; called by muse, mutect2, varscan2
- OR2G3 | c.624C>A p.V208= | Silent (SNP) | VAF 42/128 reads (33%) | called by muse, mutect2, varscan2
- PASK | c.1185G>A p.A395= | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as rs752960244; called by muse, varscan2
- PRAMEF20 | c.1017G>A p.P339= | Silent (SNP) | VAF 69/148 reads (47%) | catalogued as rs948202258; called by muse, mutect2, varscan2
- SLC22A6 | c.792C>T p.Y264= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- USP22 | c.1140G>A p.K380= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as rs1328721529; called by muse, varscan2
- ATL1 | c.-35G>T | 5'UTR (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- ATL1 | c.-34A>G | 5'UTR (SNP) | VAF 45/89 reads (51%) | called by muse, mutect2, varscan2
- CCDC93 | chr2:118014081 T>C | 5'Flank (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- DNAH17 | c.5640+11G>A | Intron (SNP) | VAF 14/100 reads (14%) | catalogued as rs758995060; called by mutect2, varscan2
- MIR6511A3 | chr16:16372449 G>A | 3'Flank (SNP) | VAF 8/41 reads (20%) | catalogued as rs1371772489; called by mutect2, varscan2
- PFKFB4 | chr3:48561110 G>A | 5'Flank (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- SLC25A48 | c.813+556C>T | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- SLC4A8 | c.2172+4996A>G | Intron (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- WASF4P | n.883G>C | RNA (SNP) | VAF 11/54 reads (20%) | catalogued as rs373492016; called by muse, mutect2, varscan2
